Somatic mutation profile of tumor specimen MP2PRT-PAVSIH-TMP1-A (aliquot MP2PRT-PAVSIH-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVSIH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.3 years (2,651 days).
Specimen MP2PRT-PAVSIH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19b75d29-4bcc-432a-b082-31501a6b7ab0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVSIH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVSIH-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5aade3c-f186-44b5-984e-a19532ea4b80

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 18, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C4orf54 | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 28/457 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as rs747939393, COSV72766762; called by muse, mutect2
- C8orf48 | c.520A>G p.N174D | Missense Mutation (SNP) | VAF 105/346 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs750434020; called by muse, mutect2, varscan2
- CACNA1A | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs866087553, COSV64205649; called by muse, mutect2
- DHX38 | c.2005C>T p.R669W | Missense Mutation (SNP) | VAF 21/253 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768906345; called by muse, mutect2
- FRAT2 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 81/262 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as rs1329356187; called by muse, mutect2, varscan2
- FTMT | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 138/398 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV58420373, COSV58421761; called by muse, mutect2, varscan2
- MEOX2 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 190/544 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV56288739; called by muse, mutect2, varscan2
- PCSK2 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 173/432 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.018); catalogued as COSV52737607; called by muse, mutect2, varscan2
- PISD | c.1097G>C p.R366P (on ENST00000439502 / NM_001326412.1; = p.R332P on NM_014338.3) | Missense Mutation (SNP) | VAF 30/428 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.756); catalogued as rs567105342, COSV56718939; called by muse, mutect2
- PLA2G2A | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.326); catalogued as rs765431164, COSV64287014; called by muse, mutect2, varscan2
- PXDNL | c.2288C>T p.A763V | Missense Mutation (SNP) | VAF 192/653 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.108); catalogued as rs1366134728, COSV62478619; called by muse, mutect2, varscan2
- SH3RF2 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 123/346 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs138966950; called by muse, mutect2, varscan2
- SPOCK1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 70/297 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs201506391, COSV56444136; called by muse, mutect2, varscan2
- UBA2 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 100/320 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55827815; called by muse, mutect2, varscan2
- CTTNBP2 | c.611A>T p.K204I | Missense Mutation (SNP) | VAF 29/366 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2
- EYS | c.7595A>T p.N2532I | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- MTTP | c.124G>T p.V42F | Missense Mutation (SNP) | VAF 131/413 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RGP1 | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 186/521 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATM | c.9120A>T p.I3040= | Silent (SNP) | VAF 34/417 reads (8%) | called by muse, mutect2
- HNRNPLL | c.240T>C p.V80= | Silent (SNP) | VAF 17/332 reads (5%) | called by muse, mutect2
- NALCN | c.4575C>T p.G1525= | Silent (SNP) | VAF 25/380 reads (7%) | catalogued as rs755090487, COSV51962126; called by muse, mutect2
- RGS7 | c.87C>T p.D29= | Silent (SNP) | VAF 38/204 reads (19%) | catalogued as rs563733368, COSV58542082; called by muse, mutect2, varscan2
- UMOD | c.1647C>T p.S549= | Silent (SNP) | VAF 91/359 reads (25%) | catalogued as rs148082440; called by muse, mutect2, varscan2
- ZNF319 | c.1473C>T p.C491= | Silent (SNP) | VAF 126/376 reads (34%) | catalogued as rs770888322; called by muse, varscan2
